Surgical pathology report (de-identified scan), TCGA case TCGA-29-1707, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1707-02A (Recurrent Tumor).

[page 1 of 2]
Surg Path

CLINICAL HISTORY:

-year-old female with malignant neoplasm of the ovary.

GROSS EXAMINATION:

A. "Proximal bowel", received fresh and placed in formalin at on is a 3.5 cm circumference x 0.7 cm length segment of gastrointestinal mucosa containing a stapled line which is removed and the specimen is submitted entirely in block A1.

B. "Pelvic mass, rectum", received fresh and placed in formalin at on is a 19 cm length x 5.5 cm circumference segment of large bowel. The deep soft tissue distally is inked blue and sectioning demonstrates a 4.5 x 4.1 x 3.1 cm well-circumscribed soft friable mass within the perirectal soft tissue. The mass is 1 cm from the colonic mucosal surface and 0.9 cm from the closest blue inked soft tissue margin. Additionally, the lesion is 3.2 cm from the distal colorectal margin and 14.1 cm from the proximal margin. Sections are submitted as follows:

BLOCK SUMMARY:

- B1- lesion with respect to blue inked deep surface
- B2-4- representative lesion
- B5- distal margin
- B6- proximal margin
- B7- representative uninvolved bowel

ICD-0-3 recurrence

adenocarcinoma, NOS 8140/3

Site: rectum and colon C19.9

2/12/15

C. "Rectal anastomosis donut", received in formalin are two fragments of pink-tan tissue, one bearing a staple line (1.5 cm diameter x 0.7 cm length) and the other fragment attached to medical instrument (1.7 cm diameter x 0.6 cm length). The stapled donut is submitted in C1 and the tissue attached to the metal device is submitted in block C2.

D. "Pelvic nodule", received fresh and placed in formalin at on is a 3.1 x 0.7 cm fragment of tan fibrofatty tissue which is trisected and submitted in block D1.

E. "Right inguinal lymph node", received fresh and placed in formalin at on is a 2.7 x 1.1 x 1 cm aggregate of tan fibrofatty tissue which is bisected and submitted in blocks E1-2.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "PROXIMAL BOWEL":

PORTION OF COLON, NEGATIVE FOR CARCINOMA.

B. "PELVIC MASS, RECTUM, PARTIAL EXCISION":

PORTION OF COLON WITH POORLY DIFFERENTIATED ADENOCARCINOMA, INVOLVING MAINLY SEROSA AND PERIRECTAL ADIPOSE TISSUE, CONSISTENT WITH RECURRENT OVARIAN ADENOCARCINOMA, SEE COMMENT.
MAXIMUM TUMOR SIZE: 4.5 CM.
MULTIPLE AREAS OF VASCULAR INVASION PRESENT.

[page 2 of 2]
C. "RECTAL ANASTOMOSIS DONUT":

PORTION OF COLON, NEGATIVE FOR CARCINOMA.

D. "PELVIC NODULE":

FIBROADIPOSE TISSUE AND LYMPH NODE, NEGATIVE FOR CARCINOMA.

E. "RIGHT INGUINAL LYMPH NODE":

TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

COMMENT: This patient has a history of poorly differentiated serous adenocarcinoma of the ovary and chemotherapy. Since the clinical impression is recurrent ovarian carcinoma, and the histologic findings are very consistent with that diagnosis, immunoperoxidase stains will not be performed on this tissue, unless requested.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file ecfecec2-de3f-4d58-917c-791ddf877daa (TCGA-29-1707.264DFD3E-7413-4DEA-A115-14887718139D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).